Surgical pathology report (de-identified scan), TCGA case TCGA-UZ-A9PZ, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University of California San Francisco, specimen TCGA-UZ-A9PZ-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

*** WITH ADDENDUM ***

Patient Name:
Med. Rec. #:
DOB:
Soc. Sec. #:
Physician(s):

Visit #:
Sex: **—**
Location:

Accession #:
Service Date:
Received:
Client:

FINAL PATHOLOGIC DIAGNOSIS

Right kidney, partial nephrectomy: Papillary renal cell carcinoma, through renal capsule, not present at margins; see comment.

COMMENT:

Kidney Tumor Synoptic Comment

- **Histologic type:** Renal cell carcinoma, papillary type.
- **Grade:** Fuhrman grading for RCC: II.
- **Tumor size:** 2.2 cm.
- **Site within kidney:** Unknown.
- **Renal pelvis:** Not applicable.
- **Ureter:** Not applicable.
- **Renal sinus:** Not applicable.
- **Hilar renal veins:** Not applicable.
- **Intrarenal veins and lymphatics:** Normal.
- **Adrenal gland:** Not present.
- **Capsule/perirenal fat:** Tumor penetrates capsule with microscopic growth in perirenal fat.
- **Lymph node status:** None present.
- **Resection margins:**
- **Ureter:** Not applicable.
- **Renal vein:** Not applicable.
- **Soft tissue:** Negative (tumor is 0.2 cm from margin).
- **Renal parenchyma:** Negative (tumor is 0.02 cm from margin).
- **AJCC/UICC Stage:** pT3aNX.

ICD O 3
Carcinoma, papillary renal cell
8260/3

Site (R) Kidney NOS
C64.9

9/23/26/14

Section(s) of renal parenchyma not involved by neoplasm will be reviewed by
with results reported by addendum.

Specimen(s) Received

[page 2 of 2]
A:Right renal mass (FS)

Intraoperative Diagnosis

IOC1 (A) Right kidney, partial nephrectomy: 2.2 cm spherical renal neoplasm, confined within capsule, 0.1 cm from parenchymal margin.

Clinical History

OR Room and Phone # (frozen specimen : intraoperative consults only): [REDACTED]

Relevant History: [REDACTED]

The patient is a [REDACTED] who, according to [REDACTED] has a 2.5 cm right renal mass found during workup for gross hematuria. [REDACTED]

The patient now undergoes partial nephrectomy.

Gross Description

The case is received fresh labeled with the patient's name, medical record number, and additionally labeled "right renal mass (fresh)" and consists of a portion of kidney (25.3 gm; size of whole specimen 7 x 4.5 x 3.5 cm; size of kidney 3 x 2.5 x 2.2 cm).

GROSS ABNORMALITIES: One, well-circumscribed, homogeneous, encapsulated, tan-yellow, firm lesion (2.2 x 2 x 1.8 cm) is identified, confined to the kidney parenchyma, 0.1 cm from the parenchymal margin and 0.2 cm from the perinephric soft tissue margin. The remaining kidney parenchyma is tan-pink and firm. The perinephric adipose tissue is deep yellow and glistening. No lymph nodes are identified.

ORIENTED BY: Unoriented

INTRAOPERATIVE FINDINGS: Intraoperative consult #1

INKING:

-Parenchymal margin-black

-Perinephric soft tissue margin-blue

POTENTIAL STUDIES: Snap frozen

CASSETTES: Representative sections are submitted cassettes as follows:

A1-A2: Lesion at closest approach to parenchymal margin.

A3-A4: Lesion at closest approach to perinephric soft tissue margin.

A5: Uninvolved kidney.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides. The attending pathologist has reviewed all dictations, including prosector work, and preliminary interpretations performed by any resident involved in the case and performed all necessary edits before signing the final report.

Electronically signed out on [REDACTED]

Addendum

Date Ordered: [REDACTED]

Date Complete: [REDACTED]

Date Reported: [REDACTED]

Status: [REDACTED]

By: [REDACTED]

Addendum Diagnosis

Addendum Comment

The section of uninvolved kidney (slide A5) was reviewed by [REDACTED] and shows no specific pathologic abnormality.

Electronical

Source: NCI Genomic Data Commons file 1cb23cc8-b25f-4a0a-9fe9-6c9e555d98d9 (TCGA-UZ-A9PZ.85BA09A1-D62B-497F-AEB8-44E9BD279A8B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).